MMRF case MMRF_1647 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c7ea860a-5aa3-4204-9d5b-8701e34cff9f

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Dead; Days to death: 936 days (2.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.0 years (29,589 days); ISS stage: III; Days to last known disease status: 936 days (2.6 years); Days to last follow up: 936 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 206 days; Days to treatment end: 239 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 344 days; Days to treatment end: 766 days (2.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 936.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 1.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 65.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.57 mg/dL; Beta 2 Microglobulin 16.2 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 522 µmol/L; Blood Urea Nitrogen 23.9 mmol/L; Calcium 2.03 mmol/L; Albumin 36 g/L; Glucose 5.78 mmol/L.
- Day 78 (ECOG 3): M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.71 mg/dL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 327 µmol/L; Blood Urea Nitrogen 33.9 mmol/L; Calcium 1.88 mmol/L; Albumin 29 g/L; Total Protein 5.4 g/dL; Glucose 4.35 mmol/L.
- Day 169 (ECOG 3): M Protein 0.49 g/dL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 62 ×10⁹/L; Creatinine 274 µmol/L; Blood Urea Nitrogen 20.7 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 5.5 g/dL; Glucose 5.5 mmol/L.
- Day 253 (ECOG 2): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.39 mg/dL; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 265 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.2 mmol/L; Albumin 28 g/L; Total Protein 6.3 g/dL; Glucose 5.89 mmol/L.
- Day 344 (ECOG 1): M Protein 0.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.85 mg/dL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 424 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.
- Day 442 (ECOG 2): M Protein 0.81 g/dL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 442 µmol/L; Blood Urea Nitrogen 23.6 mmol/L; Calcium 2.18 mmol/L; Albumin 31 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 540 (ECOG 2): Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 4.65 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 398 µmol/L; Blood Urea Nitrogen 23.6 mmol/L; Calcium 1.98 mmol/L; Albumin 31 g/L; Total Protein 5.9 g/dL; Glucose 3.58 mmol/L.
- Day 614 (ECOG 2): Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 592 µmol/L; Blood Urea Nitrogen 28.9 mmol/L; Calcium 2.03 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 722: Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 4.28 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 690 µmol/L; Blood Urea Nitrogen 27.8 mmol/L; Calcium 2.08 mmol/L; Albumin 28 g/L; Total Protein 6.3 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day -4: Weight: 86 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_1647_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1647_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
